Surgical pathology report (de-identified scan), TCGA case TCGA-SP-A6QK, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Health Network, specimen TCGA-SP-A6QK-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Copy To: [REDACTED]

Service: [REDACTED]

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Accession #: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Specimen(s) Received

1. Adrenal: left adrenal tumor

Diagnosis

Pheochromocytoma with degeneration: Adrenal (left) adrenalectomy specimen

Electronically verified by: [REDACTED]

Clinical History

Left adrenal pheochromocytoma

Gross Description

The specimen container labeled with the patient's name and as "left adrenal tumor" contains an adrenal gland that is distorted by a tumor that measures 6.5 x 6.5 x 4.2 cm. The specimen weighs 86.7 grams. On section, the tumour is dusky and hemorrhagic with a cyst measuring 4.0 cm in maximum dimension that is filled with bloody fluid. There is also a pigmented area measuring 1.0 x 0.5 x 0.4 cm. Representative sections are submitted as follows:

1A-F tumor

1G-K tumor with adrenal gland

Microscopic Description

DOMINANT LESION: adrenal tumor

SIZE: 6.5 cm maximum dimension

WEIGHT: 86.7 g

ARCHITECTURE: solid nesting "zellballen" architecture

CYTOLOGY: polygonal cells with indistinct cell borders, abundant basophilic cytoplasm and focal nuclear pleomorphism

DEGENERATION: focal hemorrhage, cystic change and fatty degeneration

ENCAPSULATION: incomplete capsule

CAPSULAR INVASION: no frank invasion identified

EXTRA-ADRENAL INVASION: not identified

RESECTION MARGINS: not involved

LYMPHOVASCULAR INVOLVEMENT: not identified

OTHER ADRENAL PATHOLOGY: none; no medullary hyperplasia

LYMPH NODES: none identified

[page 2 of 2]
Surgical Pathology Consultation Report

Source: NCI Genomic Data Commons file 478e5666-41fb-455b-b863-e59be5536ddf (TCGA-SP-A6QK.D2FAE76E-EC8E-4C56-BC73-1057E470C5F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).